Gene-level copy-number profile of specimen HCM-CSHL-0881-C20-85B from HCMI case HCM-CSHL-0881-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 64.6 years (23,582 days).
Specimen HCM-CSHL-0881-C20-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 2.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2e0c7b3b-28ae-4f3f-875c-d7c902ae0621.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0881-C20-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/fc5ad9f8-bb87-49de-a69d-ef7bd254e107

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,824; copy number 2: 47,859; copy number 3: 4,675; copy number 4: 28; copy number 5: 1; copy number 6: 10.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:201,995,696–202,144,743, 10 genes, copy number 6 (within-gene range 2–6): ELF3-AS1, MIR6740, ELF3, AL691482.3, AL691482.1, AL691482.2, Y_RNA, CRIP1P3, GPR37L1, ARL8A.
- chr11:34,853,094–34,916,379, 1 gene, copy number 5 (within-gene range 2–5): APIP.

Autosomal genes at a single copy (total copy number 1): 5,824. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
